Somatic mutation profile of tumor specimen ALCH-B3BG-TTP1-A (aliquot ALCH-B3BG-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3BG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,964 days).
Specimen ALCH-B3BG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 675e9a81-7c8a-4a55-870c-7f54b6b38471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3BG-NB1-A (Blood Derived Normal), aliquot ALCH-B3BG-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2896dc7-e74a-4d64-920b-9f0295b0d6d5

The open-access MAF lists 170 somatic variants for this specimen: 115 protein-altering or splice-affecting, 38 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 38, Intron 8, Splice Site 5, Nonsense Mutation 5, RNA 4, 3'UTR 3, Splice Region 1, 5'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 18/144 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55593468; called by muse, mutect2, varscan2
- ADAM2 | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs1554533600, COSV99698112; called by muse, mutect2, varscan2
- CCDC85A | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV68149454; called by muse, mutect2, varscan2
- CD300A | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 26/362 reads (7%) | catalogued as rs868146816; called by muse, mutect2
- CDK17 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 38/880 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1362220498; called by muse, mutect2
- CDON | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 116/1192 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.114); catalogued as rs775997399; called by muse, mutect2, varscan2
- CFAP46 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 62/624 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs777564902; called by muse, mutect2, varscan2
- DCAF12L1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421454; called by muse, mutect2, varscan2
- DOK2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480070528, COSV52389148; called by muse, mutect2, varscan2
- DUSP19 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 45/452 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.09); catalogued as rs961126713, COSV61193142; called by muse, mutect2
- GFI1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs779119308; called by muse, mutect2
- HAO1 | c.1032G>T p.M344I | Missense Mutation (SNP) | VAF 91/703 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV66493063; called by muse, mutect2, varscan2
- IL12RB1 | c.1618+1G>C p.X540_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | catalogued as rs1434654558; called by muse, mutect2
- KCNN1 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99715907; called by muse, mutect2, varscan2
- MET | c.3683A>G p.D1228G | Missense Mutation (SNP) | VAF 103/699 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59260821; called by muse, mutect2, varscan2
- MUC16 | c.9193C>A p.P3065T | Missense Mutation (SNP) | VAF 48/545 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs537336096; called by muse, mutect2
- MUC17 | c.5797G>A p.V1933I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1373371353; called by muse, mutect2
- NDUFA9 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 78/796 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369529412; called by muse, mutect2
- NR5A1 | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs369097872, COSV101007634; called by muse, mutect2, varscan2
- OR6M1 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV58434102; called by muse, mutect2
- PCDH11X | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 179/771 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53476772; called by muse, mutect2, varscan2
- PEX2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 149/1135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV63813729; called by muse, mutect2, varscan2
- PKP2 | c.2620A>T p.K874* | Nonsense Mutation (SNP) | VAF 164/1376 reads (12%) | catalogued as rs760426951, COSV99297756; called by muse, mutect2, varscan2
- PPP2R3A | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 87/589 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV53859143; called by muse, mutect2, varscan2
- PSME4 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 35/705 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as rs1239920887; called by muse, mutect2
- PWWP3B | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456524763, COSV61801713, COSV61802132; called by muse, mutect2, varscan2
- SCUBE3 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486786633, COSV51458418; called by muse, mutect2
- SLX4 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 83/727 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs112205823; called by muse, mutect2, varscan2
- SPATA31D1 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV61195211, COSV61196298; called by muse, mutect2, varscan2
- SPSB1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs763552487, COSV60164426; called by muse, mutect2
- STRN3 | c.1903A>G p.T635A (on ENST00000357479 / NM_001083893.2; = p.T551A on NM_014574.4) | Missense Mutation (SNP) | VAF 76/944 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs754762959; called by muse, mutect2
- STYXL2 | c.1263C>A p.S421R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54809153; called by muse, mutect2
- TBC1D15 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59851026; called by muse, mutect2, varscan2
- TEPSIN | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV56144803; called by mutect2, varscan2
- TIAM2 | c.4328C>T p.S1443F (on ENST00000529824; = p.S1414F on NM_012454.3) | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV51643564; called by muse, mutect2
- TTN | c.94156G>A p.G31386S (on ENST00000591111; = p.G23962S on NM_003319.4) | Missense Mutation (SNP) | VAF 74/454 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs753657854; called by muse, mutect2, varscan2
- TTN | c.32713+2T>A p.X10905_splice (on ENST00000591111; = p.X9978_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 72/848 reads (8%) | catalogued as COSV100622726; called by muse, mutect2
- UNC13B | c.2644G>T p.G882W | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1037446397, COSV65934965; called by muse, mutect2, varscan2
- VASH2 | c.495C>T p.G165= (on ENST00000517399 / NM_001301056.2; = p.G100= on NM_001136474.3) | Splice Region (SNP) | VAF 39/384 reads (10%) | catalogued as COSV55117570; called by muse, mutect2
- WDTC1 | c.1967G>T p.S656I (on ENST00000319394 / NM_001276252.2; = p.S655I on NM_015023.5) | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1322008616; called by muse, mutect2
- XIRP1 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1256762425; called by muse, mutect2
- ZIM3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs376866859; called by muse, mutect2
- ABCB1 | c.3785C>A p.A1262E | Missense Mutation (SNP) | VAF 156/1507 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ALG10B | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 136/961 reads (14%) | called by muse, mutect2, varscan2
- ANGPT4 | c.1070C>G p.A357G | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ANKRD13C | c.967A>T p.S323C | Missense Mutation (SNP) | VAF 56/870 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AP5M1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 93/807 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG9A | c.2399A>G p.H800R | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10A | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 50/471 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- BRS3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- BUD13 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.055); called by muse, mutect2
- COL15A1 | c.2794-1G>T p.X932_splice | Splice Site (SNP) | VAF 43/373 reads (12%) | called by muse, mutect2, varscan2
- COL3A1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 155/1524 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- COL4A2 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- COL5A2 | c.3755C>T p.T1252I | Missense Mutation (SNP) | VAF 108/1077 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- COPG1 | c.1299G>C p.E433D | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CWH43 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 39/547 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- CYP4F12 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.263); called by muse, mutect2
- DNAJC13 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EBLN2 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 78/829 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ELP1 | c.37A>G p.R13G | Missense Mutation (SNP) | VAF 78/596 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML5 | c.2420A>G p.E807G | Missense Mutation (SNP) | VAF 59/751 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2
- FAM205A | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FANCM | c.3060G>T p.L1020F | Missense Mutation (SNP) | VAF 162/1878 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); called by muse, mutect2
- FBXL4 | c.1658A>T p.E553V | Missense Mutation (SNP) | VAF 26/823 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- FCER2 | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- GALNT7 | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GDF2 | c.878C>G p.T293R | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGNBP2 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 45/569 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2
- GPA33 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GRK4 | c.1298T>A p.L433Q (on ENST00000398052 / NM_182982.3; = p.L401Q on NM_005307.3) | Missense Mutation (SNP) | VAF 54/546 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- HDAC5 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- HDAC9 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 70/669 reads (10%) | called by muse, mutect2, varscan2
- HERC1 | c.12494G>T p.R4165L | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HGSNAT | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFI27 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ12 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- KCNJ12 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.243); called by muse, mutect2
- KCNJ5 | c.922A>T p.M308L | Missense Mutation (SNP) | VAF 55/590 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2
- LRP1B | c.12915C>A p.N4305K | Missense Mutation (SNP) | VAF 25/359 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP1B | c.8132G>T p.R2711L | Missense Mutation (SNP) | VAF 92/1000 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- LRRTM4 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 54/736 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MAB21L1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2
- MYO15A | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); called by mutect2, varscan2
- NAB1 | c.1058G>C p.R353T | Missense Mutation (SNP) | VAF 53/838 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- NAV3 | c.1535C>G p.T512R | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); called by muse, mutect2
- NRK | c.3893T>C p.M1298T | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NVL | c.58-2A>G p.X20_splice | Splice Site (SNP) | VAF 24/239 reads (10%) | called by muse, mutect2, varscan2
- OR2L13 | c.929T>A p.L310Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- OR4N5 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OR8G5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2
- PAPOLG | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); called by muse, mutect2
- PNPLA6 | c.2211G>T p.Q737H (on ENST00000414982 / NM_001166111.2; = p.Q689H on NM_006702.5) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PNPLA6 | c.2211+1G>T p.X737_splice (on ENST00000414982 / NM_001166111.2; = p.X689_splice on NM_006702.5) | Splice Site (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- PTPN13 | c.3866A>T p.K1289I (on ENST00000411767 / NM_080683.3; = p.K1270I on NM_006264.3) | Missense Mutation (SNP) | VAF 104/1132 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2
- RARRES1 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- RC3H1 | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 67/518 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RIMS2 | c.4259T>C p.L1420P (on ENST00000666250 / NM_001348490.2; = p.L991P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/665 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SETD1A | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC12A1 | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 72/896 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SLC12A7 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- SNED1 | c.1375T>G p.F459V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2
- TAF1 | c.3199A>T p.T1067S (on ENST00000373790 / NM_138923.4; = p.T1088S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TDRD15 | c.4103T>C p.L1368S | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TDRD15 | c.5271C>A p.D1757E | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TEX13C | c.950del p.K317Rfs*10 | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | called by mutect2, pindel, varscan2
- TRH | c.500G>C p.W167S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2
- TSEN54 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 65/518 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TTN | c.17434A>G p.I5812V (on ENST00000591111; = p.I4885V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/1612 reads (9%) | PolyPhen benign (0); called by muse, mutect2
- USP20 | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR47 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZCCHC12 | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZCCHC2 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZGRF1 | c.3193C>G p.Q1065E | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB11 | c.3006T>C p.Y1002= | Silent (SNP) | VAF 46/509 reads (9%) | called by muse, mutect2
- ABO | c.729C>T p.F243= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- ATXN1 | c.801C>T p.P267= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs150320597, COSV99786299; called by mutect2, varscan2
- CD1E | c.42T>C p.P14= | Silent (SNP) | VAF 25/220 reads (11%) | catalogued as COSV100936925; called by muse, mutect2, varscan2
- CHST8 | c.183C>A p.G61= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs139487059; called by mutect2, varscan2
- CHTF18 | c.81A>G p.A27= | Silent (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- CUL1 | c.1668G>C p.P556= | Silent (SNP) | VAF 58/488 reads (12%) | called by muse, mutect2, varscan2
- DNAH11 | c.5616T>C p.T1872= | Silent (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- DNAH8 | c.5139T>C p.R1713= | Silent (SNP) | VAF 48/510 reads (9%) | catalogued as rs1382429820; called by muse, mutect2
- DPPA4 | c.675C>A p.A225= | Silent (SNP) | VAF 52/532 reads (10%) | called by muse, mutect2, varscan2
- F13B | c.1938T>C p.C646= | Silent (SNP) | VAF 85/848 reads (10%) | called by muse, mutect2, varscan2
- FGF9 | c.393C>A p.T131= | Silent (SNP) | VAF 50/540 reads (9%) | catalogued as COSV101211035; called by muse, mutect2
- FHL5 | c.573C>A p.G191= | Silent (SNP) | VAF 32/434 reads (7%) | catalogued as COSV58735480; called by muse, mutect2
- FSCB | c.1344C>G p.T448= | Silent (SNP) | VAF 55/707 reads (8%) | called by muse, mutect2
- HSP90AA1 | c.975A>G p.A325= | Silent (SNP) | VAF 23/259 reads (9%) | catalogued as rs115927657; called by muse, mutect2
- KIAA1671 | c.5052G>T p.T1684= | Silent (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- KIF17 | c.1836G>T p.L612= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- MMP16 | c.1458T>C p.S486= | Silent (SNP) | VAF 42/448 reads (9%) | catalogued as COSV54184354; called by muse, mutect2
- MOV10L1 | c.831G>A p.T277= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs1336737582, COSV99435314; called by muse, mutect2
- MUC16 | c.1467C>T p.T489= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as rs537710578; called by muse, mutect2, varscan2
- NAT8L | c.228C>T p.R76= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV59051382; called by muse, mutect2
- NRXN1 | c.1020C>T p.V340= | Silent (SNP) | VAF 78/963 reads (8%) | catalogued as COSV58475481; called by muse, mutect2
- OR2G2 | c.288C>A p.A96= | Silent (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- P3H3 | c.555C>T p.P185= | Silent (SNP) | VAF 79/574 reads (14%) | catalogued as rs782319186; called by muse, mutect2, varscan2
- PCLO | c.1146A>T p.S382= | Silent (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2
- PGR | c.1089C>T p.Y363= | Silent (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- RNF215 | c.951C>A p.L317= | Silent (SNP) | VAF 14/291 reads (5%) | called by muse, mutect2
- RTL9 | c.3759C>T p.A1253= | Silent (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- SAP18 | c.57G>A p.P19= (on ENST00000607003; = p.P38= on NM_005870.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs376020479; called by muse, mutect2, varscan2
- SCARF2 | c.2037C>T p.A679= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- SLC39A12 | c.513C>T p.T171= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, varscan2
- SPTBN2 | c.2430A>T p.A810= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- TMEM132D | c.2442A>T p.A814= | Silent (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- TRIM43B | c.51C>A p.I17= | Silent (SNP) | VAF 58/814 reads (7%) | called by muse, mutect2
- TRIM58 | c.741G>T p.L247= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- TRMT1 | c.507A>T p.R169= | Silent (SNP) | VAF 28/189 reads (15%) | called by muse, varscan2
- UBR7 | c.711A>G p.K237= | Silent (SNP) | VAF 84/725 reads (12%) | called by muse, mutect2, varscan2
- ZIC2 | c.135G>A p.A45= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- AKAP9 | c.10968+51A>G | Intron (SNP) | VAF 42/372 reads (11%) | called by muse, mutect2, varscan2
- C8orf86 | n.668A>G | RNA (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- CCT5 | c.1499-24A>T | Intron (SNP) | VAF 70/946 reads (7%) | called by muse, mutect2
- CLEC4D | c.-13G>T | 5'UTR (SNP) | VAF 19/237 reads (8%) | catalogued as rs1008273479; called by muse, mutect2
- CPLANE1 | c.*4832A>G | 3'UTR (SNP) | VAF 34/506 reads (7%) | called by muse, mutect2
- FAM90A27P | n.1019G>T | RNA (SNP) | VAF 58/515 reads (11%) | catalogued as rs556878566; called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1485G>T | Intron (SNP) | VAF 11/81 reads (14%) | catalogued as rs891998788; called by muse, mutect2, varscan2
- L34079.1 | c.169+14137C>T | Intron (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- MIR506 | n.46G>T | RNA (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+323T>C | Intron (SNP) | VAF 204/867 reads (24%) | catalogued as rs780329575; called by mutect2, varscan2
- NDUFB10 | chr16:1965280 G>C | 3'Flank (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- OR2L1P | n.895A>G | RNA (SNP) | VAF 37/720 reads (5%) | called by muse, mutect2
- PROM1 | c.221-16412C>A | Intron (SNP) | VAF 34/426 reads (8%) | called by muse, mutect2
- RYR2 | c.11145+1266C>A | Intron (SNP) | VAF 38/474 reads (8%) | called by muse, mutect2
- SCAF8 | c.30+8069G>T | Intron (SNP) | VAF 28/496 reads (6%) | called by muse, mutect2
- SLC4A10 | c.*85T>A | 3'UTR (SNP) | VAF 64/710 reads (9%) | called by muse, mutect2
- TOX3 | c.*277G>T | 3'UTR (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
